MMRF case MMRF_1683 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/acf4c817-cf4f-4a52-b781-d8360e570b2f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.8 years (26,234 days); ISS stage: II; Days to last known disease status: 1,122 days (3.1 years); Days to last follow up: 1,122 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 135 days; Days to treatment end: 135 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 136 days; Days to treatment end: 136 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -34 (ECOG 0): M Protein 6.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.016 mg/dL; Immunoglobulin G 65.6 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.91 g/L; Beta 2 Microglobulin 3.8 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 11.8 g/dL; Glucose 5.01 mmol/L.
- Day 64 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.177 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.159 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 1.77 g/L; Beta 2 Microglobulin 2.71 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 7.7 g/dL; Glucose 4.95 mmol/L.
- Day 151 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 1.26 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 4.85 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.58 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.95 mmol/L; Albumin 25 g/L; Total Protein 5 g/dL; Glucose 5.34 mmol/L.
- Day 289 (ECOG 0): Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 196 ×10⁹/L.
- Day 381 (ECOG 0): Hemoglobin 9.05 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 182 ×10⁹/L.
- Day 513 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 2.06 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 652 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 2.16 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.28 mmol/L.
- Day 835 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 2.38 g/L; Beta 2 Microglobulin 1.97 µg/mL; Hemoglobin 9.24 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 5.67 mmol/L.
- Day 949 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 2.29 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 1,122 (ECOG 1): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 2.25 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -34: Weight: 90 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1683_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_1683_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
